CPTAC case C3N-03205 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0319896f-294b-4c76-853a-17592698a88c

Demographics
Sex at birth: female; Race: asian; Year of birth: 1974; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 43.2 years (15,778 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,846 days (5.1 years); Progression or recurrence: yes; Days to last follow up: 1,846 days (5.1 years); Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 3.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 23; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (6 entries)
- Days to follow up: 372 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 749 days (2.1 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 749 days (2.1 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 385 days (1.1 years); Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 1,126 days (3.1 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 1,432 days (3.9 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.
- Days to follow up: 1,846 days (5.1 years); Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 2.

Other clinical attributes
- Weight: 48 kg; Height: 157 cm; BMI: 19.47; FEV1/FVC before bronchodilator (%): 92.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03205-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 242 mg; Time between clamping and freezing: 22 minutes; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03205-21: Section location: left upper lobe and left lower lobe; Percent tumor nuclei: 85; Percent necrosis: 0.
- Sample C3N-03205-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 293 mg; Time between clamping and freezing: 22 minutes; Time between excision and freezing: 13 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03205-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
